Gene-level copy-number profile of tumor specimen ALCH-B4C7-TTP1-A from ALCHEMIST case ALCH-B4C7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.4 years (27,529 days).
Specimen ALCH-B4C7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 68958534-492c-4ce9-a9db-7da2395b6c91.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4C7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/525a6de5-011f-4303-970e-b00a42fc11e3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 13; copy number 2: 749; copy number 3: 10,469; copy number 4: 14,354; copy number 5: 12,117; copy number 6: 11,616; copy number 7: 3,033; copy number 8: 5,316; copy number 9: 1,178; copy number 10: 8; copy number 11: 5; copy number 12: 1; copy number 13: 1; copy number 14: 7; copy number 16: 2.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–180,970,762, 2 genes: AC091874.2, AC091874.1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–6): AL359922.1.
- chr9:21,929,457–21,995,301, 3 genes (within-gene range 0–6): ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes (within-gene range 0–5): AL449423.1, CDKN2B, UBA52P6.
- chr9:61,330,717–61,453,030, 2 genes: CNTNAP3C, RN7SL462P.
- chr9:61,615,835–61,627,683, 1 gene: FAM242D.
- chr15:25,176,832–25,182,466, 4 genes (within-gene range 0–4): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7.
- chr15:25,193,321–25,193,402, 1 gene (within-gene range 0–4): SNORD115-13.
- chr15:25,199,448–25,209,999, 7 genes (within-gene range 0–4): SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22.
- chr16:67,148,104–67,165,815, 4 genes (within-gene range 0–3): B3GNT9, TRADD, FBXL8, AC074143.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,202 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,548,756–248,601,869, 7 genes, copy number 14: AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2.
- chr3:129,647,792–198,123,232, 1,167 genes, copy number 9–11 (broad region; genes not listed).
- chr8:140,657,900–141,002,216, 4 genes, copy number 10 (within-gene range 7–10): PTK2, MIR151A, AC105235.1, RNA5SP278.
- chr9:136,728,953–136,748,525, 5 genes, copy number 10–16: AL355987.5, LCN10, AL355987.1, LCN6, MIR6722.
- chr9:136,759,634–136,780,218, 2 genes, copy number 9–10: LCN15, ATP6V1G1P3.
- chr16:1,088,226–1,096,244, 1 gene, copy number 13: C1QTNF8.
- chr19:984,332–1,174,268, 13 genes, copy number 9: WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4, SBNO2.
- chr19:1,228,287–1,238,027, 1 gene, copy number 12 (within-gene range 6–12): CBARP.
- chr19:1,259,384–1,274,880, 2 genes, copy number 9: CIRBP, CIRBP-AS1.

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
